Gene-level copy-number profile of tumor specimen ALCH-B3ZL-TTP1-A from ALCHEMIST case ALCH-B3ZL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.0 years (27,038 days).
Specimen ALCH-B3ZL-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9fa39895-6bcd-449b-8546-03444f032232.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3ZL-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,252 have no estimate.
https://portal.gdc.cancer.gov/files/56085704-48a8-4c24-9d94-6fceb82bc9d5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 43; copy number 1: 4,127; copy number 2: 53,479; copy number 3: 696; copy number 4: 10; copy number 5: 2; copy number 6: 2; copy number 9: 1; copy number 12: 1; copy number 17: 9; copy number 43: 1.

Homozygous deletions (total copy number 0; autosomes only): 29 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:91,578,478–91,685,884, 6 genes: AC233266.1, AC233266.2, AC116050.1, LSP1P4, RNA5SP100, DRD5P1.
- chr7:140,645,829–140,646,126, 1 gene (within-gene range 0–1): RN7SL771P.
- chr8:69,942,948–69,944,648, 1 gene: SDCBPP2.
- chr8:70,077,906–70,078,032, 1 gene: RNU1-101P.
- chr12:120,914,400–120,917,236, 2 genes: CLIC1P1, RPL12P33.
- chr15:22,225,278–22,225,329, 1 gene: MIR1268A.
- chr15:57,300,365–57,326,447, 3 genes: LINC00926, LINC01413, NDUFB10P1.
- chr16:46,469,341–46,575,094, 4 genes: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1.
- chr16:58,665,109–58,684,770, 1 gene: SLC38A7.
- chr19:186,373–246,544, 4 genes: SEPTIN14P19, CICP19, LINC01002, RNU6-1076P.
- chr19:3,567,278–3,579,088, 3 genes (within-gene range 0–2): AC005786.4, AC005786.1, HMG20B.
- chr19:3,594,507–3,606,875, 1 gene: TBXA2R.
- chr22:42,364,390–42,369,284, 1 gene: LINC01315.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 16 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:242,175,181–242,175,634, 1 gene, copy number 5: RPL23AP88.
- chr16:29,425,800–29,447,026, 1 gene, copy number 17: SMG1P6.
- chr16:29,443,056–29,505,999, 11 genes, copy number 6–17: BOLA2, BOLA2-SMG1P6, AC133555.4, SLX1B, SLX1B-SULT1A4, SULT1A4, AC133555.3, AC133555.5, AC133555.2, AC133555.1, NPIPB12.
- chr17:63,454,993–63,455,817, 1 gene, copy number 5: AC005828.5.
- chr19:3,607,247–3,613,930, 1 gene, copy number 12 (within-gene range 4–12): CACTIN-AS1.
- chr19:40,216,058–40,218,399, 1 gene, copy number 43: TTC9B.

Autosomal genes at a single copy (total copy number 1): 4,053. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
